Somatic mutation profile of tumor specimen TCGA-CC-A7IK-01A (aliquot TCGA-CC-A7IK-01A-12D-A33Q-10) from TCGA case TCGA-CC-A7IK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 59.0 years (21,552 days).
Specimen TCGA-CC-A7IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f3ebfb2-bc4e-4b15-8e3f-81337ae9e42d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7IK-10A (Blood Derived Normal), aliquot TCGA-CC-A7IK-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f89c675a-dc23-4165-9098-42887046073d

The open-access MAF lists 345 somatic variants for this specimen: 273 protein-altering or splice-affecting, 69 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 69, Nonsense Mutation 17, Splice Site 8, Splice Region 4, Frame Shift Del 3, Frame Shift Ins 3, Intron 2, 5'UTR 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 33/158 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1450A>G p.K484E | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV64675457; called by muse, mutect2, varscan2
- ABCC2 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1210667442, COSV64971270; called by muse, mutect2, varscan2
- ABCG1 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV59204728, COSV59209418; called by muse, mutect2, varscan2
- AC011455.2 | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV55501337; called by muse, mutect2
- ADAM32 | c.572A>G p.H191R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1234089706, COSV65953021; called by muse, mutect2, varscan2
- ADAMDEC1 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56477148; called by muse, mutect2, varscan2
- ADAMTS7 | c.3008C>A p.P1003H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV66309099; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1645T>A p.W549R | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54465187; called by muse, mutect2, varscan2
- ADAR | c.1935-2A>G p.X645_splice | Splice Site (SNP) | VAF 34/76 reads (45%) | catalogued as CS090036, COSV52719928; called by muse, mutect2, varscan2
- ADCY8 | c.2641T>C p.F881L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); catalogued as COSV53923246; called by muse, mutect2, varscan2
- ADGRB3 | c.4280T>C p.V1427A | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53242823, COSV53257323; called by muse, mutect2, varscan2
- ADGRF5 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs375753155; called by muse, mutect2, varscan2
- AGO3 | c.589A>T p.R197W | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55796407; called by muse, mutect2, varscan2
- AHNAK2 | c.12982G>A p.V4328M | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.715); catalogued as rs769614137, COSV60927320; called by muse, mutect2, varscan2
- AJM1 | c.1517T>C p.L506P | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56034615; called by muse, mutect2, varscan2
- AKAP4 | c.1136T>C p.V379A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1557203994, COSV62075353; called by muse, mutect2, varscan2
- AKR1D1 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV54340238; called by muse, mutect2, varscan2
- ALPP | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67396798, COSV67397690; called by muse, mutect2, varscan2
- AMFR | c.975-2A>T p.X325_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV51923806; called by muse, mutect2, varscan2
- AP2B1 | c.37G>T p.G13* | Nonsense Mutation (SNP) | VAF 58/300 reads (19%) | catalogued as COSV52002564; called by muse, mutect2, varscan2
- ARHGAP22 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50972911; called by muse, mutect2, varscan2
- ARHGAP39 | c.2713G>A p.E905K (on ENST00000276826 / NM_001308208.2; = p.E936K on NM_025251.2) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs144988605, COSV52775006; called by muse, mutect2, varscan2
- ARHGAP39 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as rs1305895460, COSV52774125, COSV52775016; called by muse, mutect2, varscan2
- ARMCX6 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62680908; called by muse, mutect2
- ASAP3 | c.1706A>C p.N569T | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV60877408; called by muse, mutect2, varscan2
- ASPM | c.2374A>T p.R792W | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54136828; called by muse, mutect2, varscan2
- ATCAY | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV56658521; called by muse, mutect2, varscan2
- ATP12A | c.2774A>G p.Q925R | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV54521663; called by muse, mutect2, varscan2
- ATP2B2 | c.3130A>T p.S1044C (on ENST00000352432; = p.S1010C on NM_001683.5) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59505728; called by muse, mutect2, varscan2
- ATP8B3 | c.312A>C p.A104= | Splice Region (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100034223; called by muse, mutect2, varscan2
- ATP9A | c.1582A>G p.T528A | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV58770862; called by muse, mutect2, varscan2
- ATP9B | c.961A>T p.S321C | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56959338; called by muse, mutect2, varscan2
- AZGP1 | c.179G>T p.R60I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV52799093; called by muse, mutect2, varscan2
- BDKRB2 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV60014927; called by muse, mutect2, varscan2
- BRINP2 | c.1825A>C p.S609R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV64179663; called by muse, mutect2, varscan2
- BSN | c.9077C>G p.T3026S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV56525751; called by muse, mutect2, varscan2
- BTLA | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV57939999; called by muse, mutect2, varscan2
- CA1 | c.235+2T>A p.X79_splice | Splice Site (SNP) | VAF 13/88 reads (15%) | catalogued as COSV56279846; called by muse, mutect2, varscan2
- CAD | c.2770A>G p.T924A | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1446576025, COSV53030893; called by muse, mutect2, varscan2
- CAND1 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73338656; called by muse, mutect2, varscan2
- CCDC151 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV52953528; called by muse, mutect2, varscan2
- CCDC30 | c.1940A>T p.Q647L (on ENST00000340612; = p.Q604L on NM_001080850.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV59608955; called by muse, mutect2
- CCDC88B | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV57267708; called by muse, mutect2, varscan2
- CCDC92 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV53021709; called by muse, mutect2, varscan2
- CCN4 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205065236, COSV51535010; called by muse, mutect2, varscan2
- CDCP1 | c.81A>T p.A27= | Splice Region (SNP) | VAF 13/76 reads (17%) | catalogued as COSV56107526; called by muse, mutect2, varscan2
- CELSR3 | c.5745C>A p.C1915* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV51135192; called by muse, mutect2, varscan2
- CEP152 | c.3995A>T p.E1332V (on ENST00000380950 / NM_001194998.2; = p.E1276V on NM_014985.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57863395; called by muse, mutect2, varscan2
- CES5A | c.724A>T p.K242* | Nonsense Mutation (SNP) | VAF 15/115 reads (13%) | catalogued as rs1326970851, COSV51869696; called by muse, mutect2, varscan2
- CFAP43 | c.4402A>T p.I1468L | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs750109033, COSV63854728; called by mutect2, varscan2
- CHD5 | c.1773G>A p.W591* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV52423011; called by muse, mutect2, varscan2
- CHMP5 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.529); catalogued as rs1308332442, COSV56303685; called by muse, mutect2, varscan2
- CHRM2 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV57782211; called by muse, mutect2, varscan2
- CLCN1 | c.841A>G p.T281A | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV58373711; called by muse, mutect2, varscan2
- CLPTM1 | c.515A>G p.K172R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.434); catalogued as COSV61611277; called by muse, mutect2, varscan2
- CLSTN2 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101515729, COSV71724212; called by muse, mutect2, varscan2
- CR2 | c.2581A>C p.N861H | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV100889563; called by muse, mutect2, varscan2
- CRACDL | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67409821; called by muse, mutect2, varscan2
- CTDP1 | c.418A>T p.K140* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV50008173; called by muse, mutect2
- CYP3A5 | c.179T>G p.F60C | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1368152429, COSV56122546; called by muse, mutect2, varscan2
- DCDC1 | c.2986A>G p.R996G (on ENST00000597505 / NM_001367979.1; = p.R103G on NM_020869.3) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV60311391; called by muse, mutect2, varscan2
- DDI1 | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV56391076; called by muse, mutect2
- DDN | c.1565A>T p.Q522L | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.169); catalogued as COSV60294370; called by muse, mutect2, varscan2
- DIDO1 | c.4531A>G p.M1511V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV56632140; called by muse, mutect2, varscan2
- DMD | c.3383A>T p.E1128V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV63784450; called by muse, mutect2, varscan2
- DMRTB1 | c.962-2A>T p.X321_splice | Splice Site (SNP) | VAF 104/215 reads (48%) | catalogued as COSV65113859; called by muse, mutect2, varscan2
- DMXL1 | c.6913A>T p.N2305Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV60719334; called by muse, mutect2, varscan2
- DNA2 | c.2082A>G p.I694M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1178934359, COSV64429851; called by muse, mutect2, varscan2
- DNAH17 | c.10862A>T p.E3621V | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67760017; called by muse, mutect2, varscan2
- DSE | c.1859A>G p.D620G | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59063790; called by muse, mutect2, varscan2
- EFTUD2 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs780542105, COSV68184513; called by muse, mutect2, varscan2
- EIF3A | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.138); catalogued as COSV64962924; called by muse, mutect2, varscan2
- ELL2 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1192274694, COSV52984696; called by muse, mutect2, varscan2
- ELSPBP1 | c.412A>T p.N138Y | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV60414808; called by muse, mutect2, varscan2
- EPHA8 | c.95-1G>A p.X32_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as COSV51290829; called by muse, mutect2, varscan2
- EPHB3 | c.2627T>G p.V876G | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV57808641; called by muse, mutect2
- FAM161B | c.1011G>C p.Q337H (on ENST00000651776; = p.Q274H on NM_152445.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV54103940; called by muse, mutect2, varscan2
- FBXW10 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.121); catalogued as COSV57320259; called by muse, mutect2
- FGA | c.992C>A p.T331N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.201); catalogued as COSV57399904; called by muse, mutect2, varscan2
- FGFR2 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM960649, COSV60656856; called by muse, mutect2, varscan2
- FIG4 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57790478; called by muse, mutect2, varscan2
- FLG | c.2446G>C p.V816L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs769144771, COSV100911269, COSV100912446; called by muse, varscan2
- FNDC1 | c.1210A>C p.K404Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51945931; called by muse, mutect2, varscan2
- FOXK1 | c.2009A>T p.K670M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV61068189; called by muse, varscan2
- FSCN1 | c.950T>A p.L317Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61018562; called by muse, mutect2, varscan2
- FUT3 | c.1045A>T p.R349W | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV54607851; called by muse, mutect2, varscan2
- FUT9 | c.886A>T p.S296C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV56150618, COSV56154545; called by muse, mutect2, varscan2
- GABRA4 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV51933753; called by muse, mutect2, varscan2
- GALNT11 | c.1171G>C p.G391R | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as COSV57428062; called by muse, mutect2, varscan2
- GCC1 | c.1667T>A p.L556Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); catalogued as COSV58463592; called by muse, mutect2, varscan2
- GCN1 | c.6491A>G p.E2164G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV56113594; called by muse, mutect2, varscan2
- GH2 | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV60427665; called by muse, mutect2, varscan2
- GIMAP8 | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56233317; called by muse, mutect2, varscan2
- GLP2R | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1384619512, COSV52328739; called by muse, mutect2, varscan2
- GOLGA7B | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54008350; called by muse, mutect2, varscan2
- GPAT4 | c.776G>A p.S259N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0.029); catalogued as COSV67841819; called by muse, mutect2, varscan2
- GPR161 | c.1556A>C p.E519A | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV54793563; called by muse, mutect2, varscan2
- GPR3 | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64995135; called by muse, mutect2, varscan2
- GTF3C6 | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as rs1410220748, COSV100328701; called by muse, mutect2
- GZMB | c.366A>T p.R122S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV53543182; called by muse, mutect2, varscan2
- H3C11 | c.355A>C p.T119P | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100137983, COSV58901247; called by muse, mutect2, varscan2
- HERC1 | c.6868G>T p.D2290Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV71247717, COSV71249780; called by muse, mutect2, varscan2
- HERC1 | c.5443A>T p.S1815C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.62); catalogued as COSV71249781; called by muse, mutect2, varscan2
- HIVEP2 | c.5179T>C p.F1727L | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV50044550; called by muse, mutect2, varscan2
- HPN | c.466A>T p.R156W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52885627; called by muse, mutect2, varscan2
- HTR1B | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV64051840; called by muse, mutect2, varscan2
- IGFN1 | c.3619G>T p.D1207Y (on ENST00000295591 / NM_001367841.1; = p.D3664Y on NM_001164586.2) | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55178692, COSV55182361; called by muse, mutect2, varscan2
- IGLON5 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54538290; called by muse, mutect2, varscan2
- IGSF3 | c.1682C>G p.S561C (on ENST00000369486 / NM_001007237.3; = p.S581C on NM_001542.4) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59585375, COSV59596206; called by muse, mutect2, varscan2
- IGSF6 | c.535T>A p.S179T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV51679987; called by muse, mutect2, varscan2
- IL36G | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV52079166, COSV52079469; called by muse, mutect2, varscan2
- IMPA1 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56272690; called by muse, mutect2, varscan2
- IMPG2 | c.3610G>T p.E1204* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV51984130; called by muse, mutect2, varscan2
- IMPG2 | c.1055G>T p.S352I | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV51984139; called by muse, mutect2, varscan2
- ITIH6 | c.2518C>G p.L840V | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV54493471; called by muse, mutect2, varscan2
- JAKMIP1 | c.1706A>T p.K569M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV51543124; called by muse, mutect2, varscan2
- JARID2 | c.2062A>G p.R688G | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV59196290; called by muse, mutect2, varscan2
- KCNJ14 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60738756; called by muse, mutect2, varscan2
- KCNT1 | c.359C>A p.P120Q (on ENST00000488444; = p.P139Q on NM_020822.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV53708963; called by muse, mutect2
- KEAP1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1040740503, COSV50633622, COSV50635967, COSV50650015; called by muse, mutect2, varscan2
- KHSRP | c.1472T>C p.I491T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67920273; called by muse, mutect2, varscan2
- KIAA1109 | c.7186A>C p.N2396H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52688662; called by muse, mutect2, varscan2
- KNTC1 | c.4580A>G p.Y1527C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61083353; called by muse, mutect2
- KRT1 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.99); catalogued as rs557388955, COSV52868809; called by muse, mutect2, varscan2
- KRT19 | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV64239149; called by muse, mutect2, varscan2
- KRT31 | c.25A>T p.S9C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV52437716; called by muse, mutect2
- KRT71 | c.1380T>G p.S460R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs756551310, COSV57292558; called by muse, mutect2, varscan2
- L3MBTL3 | c.1675T>C p.S559P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62388444; called by muse, mutect2, varscan2
- LAMA5 | c.7885A>G p.I2629V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs983407158, COSV53370019; called by muse, mutect2, varscan2
- LAMB2 | c.1633C>G p.Q545E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.024); catalogued as COSV59736974; called by muse, mutect2, varscan2
- LATS2 | c.2867A>T p.D956V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV66878929; called by muse, mutect2, varscan2
- LFNG | c.719T>A p.V240D (on ENST00000222725 / NM_001040167.2; = p.V111D on NM_002304.2) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV56070706; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.321C>A p.I107= | Splice Region (SNP) | VAF 19/75 reads (25%) | catalogued as rs1440365962, COSV53284731; called by muse, mutect2, varscan2
- LIPE | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1319569762, COSV54924851; called by muse, mutect2, varscan2
- LMX1B | c.1144C>A p.Q382K (on ENST00000373474 / NM_001174147.2; = p.Q375K on NM_002316.4) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV62741459; called by muse, mutect2, varscan2
- LRP1B | c.6214G>T p.G2072* | Nonsense Mutation (SNP) | VAF 58/247 reads (23%) | catalogued as COSV67263701; called by muse, mutect2, varscan2
- LRRC56 | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV54246124; called by muse, mutect2, varscan2
- LRRK1 | c.1831C>A p.P611T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52624090; called by muse, mutect2, varscan2
- LRTM1 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV55573155; called by muse, mutect2, varscan2
- MAGEC1 | c.3353T>C p.I1118T | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1279422292, COSV53579704; called by muse, varscan2
- MAN2A1 | c.322T>G p.S108A | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV54857260; called by muse, mutect2, varscan2
- MARK4 | c.1064A>T p.Q355L | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV53467828; called by muse, mutect2
- MEFV | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747515115, COSV54826361; called by muse, mutect2, varscan2
- MEGF8 | c.2365G>T p.A789S (on ENST00000251268 / NM_001271938.2; = p.A722S on NM_001410.3) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52098664; called by muse, mutect2, varscan2
- MFAP5 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 65/79 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV63946168; called by muse, mutect2, varscan2
- MFSD6 | c.1894A>G p.K632E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.06); catalogued as COSV55624740; called by muse, mutect2, varscan2
- MICAL1 | c.2692A>T p.K898* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV57806774; called by muse, mutect2, varscan2
- MLC1 | c.847A>C p.I283L | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs774026753, COSV61118535; called by muse, mutect2, varscan2
- MMP27 | c.363T>A p.D121E | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV52782413; called by muse, mutect2, varscan2
- MPO | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51861822, COSV99229160; called by muse, mutect2, varscan2
- MRPS21 | c.28A>T p.R10W | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV58414505; called by muse, mutect2
- MXRA5 | c.3446G>T p.R1149M | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV54246879; called by muse, mutect2, varscan2
- MXRA8 | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58511532; called by muse, mutect2, varscan2
- NAV1 | c.3164A>G p.D1055G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV55224361; called by muse, mutect2, varscan2
- NEB | c.6476T>C p.M2159T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV51451663, COSV51460250; called by muse, mutect2, varscan2
- NEDD1 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as rs889272984, COSV57146234; called by muse, mutect2, varscan2
- NF1 | c.2388A>C p.K796N | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV62217093; called by muse, mutect2, varscan2
- NIPSNAP3B | c.438T>A p.Y146* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV66106860; called by muse, mutect2, varscan2
- NKD2 | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV56894611; called by muse, mutect2, varscan2
- NOS2 | c.2704A>T p.I902F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV58226800; called by muse, mutect2, varscan2
- NOTCH4 | c.5411C>T p.A1804V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV66683214; called by muse, mutect2, varscan2
- NPS | c.270A>T p.*90Cext*17 | Nonstop Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV67690842; called by muse, mutect2, varscan2
- NR1H3 | c.1130A>C p.Q377P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as COSV60628974; called by muse, mutect2, varscan2
- NRG1 | c.187G>A p.E63K (on ENST00000523534; = p.E210K on NM_013962.2) | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs778215426, COSV73065384; called by muse, mutect2, varscan2
- OBSCN | c.18689A>C p.E6230A | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52817423; called by muse, mutect2, varscan2
- OGN | c.644T>A p.L215H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52761738; called by muse, mutect2, varscan2
- OLFM3 | c.1385T>A p.V462E (on ENST00000338858 / NM_001288821.1; = p.V442E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58802674; called by muse, mutect2, varscan2
- OR3A1 | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 58/71 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60163675; called by muse, mutect2, varscan2
- OR52A1 | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1259508514, COSV61093133; called by muse, mutect2, varscan2
- OTUD7A | c.1895T>G p.L632R (on ENST00000307050 / NM_001382637.1; = p.L625R on NM_130901.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61042599; called by muse, mutect2, varscan2
- P4HA2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370556720; called by muse, mutect2, varscan2
- PACC1 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs780645684, COSV54789312; called by muse, mutect2, varscan2
- PCDHB1 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV60632841; called by muse, mutect2, varscan2
- PCDHB8 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.013); catalogued as COSV50806126; called by muse, mutect2, varscan2
- PDE11A | c.1072-2A>T p.X358_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV53705787; called by muse, mutect2, varscan2
- PHTF1 | c.2182A>T p.N728Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63654686; called by muse, mutect2, varscan2
- PKD1L1 | c.6371A>G p.Q2124R | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56975510; called by muse, mutect2, varscan2
- PLA2G4D | c.2061G>T p.E687D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.15); catalogued as COSV51823068; called by muse, mutect2
- PLCB4 | c.913T>A p.F305I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53814589; called by muse, mutect2, varscan2
- PLIN3 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs750604861, COSV55736879; called by muse, mutect2, varscan2
- PLIN4 | c.2092A>T p.K698* (on ENST00000301286; = p.K713* on NM_001367868.2) | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV56697511; called by muse, varscan2
- POLR2I | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs1475908364, COSV52900699; called by muse, mutect2
- PPDPFL | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV57462085; called by muse, mutect2, varscan2
- PPFIA4 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99829728; called by muse, mutect2, varscan2
- PPP6C | c.238-2A>T p.X80_splice | Splice Site (SNP) | VAF 8/102 reads (8%) | catalogued as COSV65208889; called by muse, mutect2
- PRKAA1 | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.599); catalogued as rs373496949; called by muse, mutect2, varscan2
- PRR12 | c.2447A>T p.D816V (on ENST00000615927; = p.D1637V on NM_020719.3) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69819776; called by muse, mutect2, varscan2
- PRSS22 | c.848C>A p.S283Y | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV50723544; called by muse, mutect2, varscan2
- PTBP2 | c.1084A>G p.S362G (on ENST00000426398 / NM_001300986.2; = p.S354G on NM_021190.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.904); catalogued as COSV64626185; called by muse, mutect2, varscan2
- PTK2 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs747807231, COSV61790818; called by muse, mutect2, varscan2
- PTK2B | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1355184213, COSV57764189; called by muse, mutect2, varscan2
- PTPN14 | c.3291G>T p.Q1097H | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV65287438; called by muse, mutect2, varscan2
- PTPRA | c.830-2A>T p.X277_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV53787114; called by muse, mutect2, varscan2
- QRICH1 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as COSV62617348; called by muse, mutect2, varscan2
- RAB18 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV63613961; called by muse, mutect2, varscan2
- RACGAP1 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56700804; called by muse, mutect2, varscan2
- RBM3 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63202792; called by muse, mutect2, varscan2
- REV1 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs963304534, COSV51489340; called by muse, mutect2, varscan2
- REV3L | c.3079G>T p.V1027F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62622361; called by muse, mutect2, varscan2
- RFC1 | c.1457A>G p.K486R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62900830; called by muse, mutect2, varscan2
- RNASE10 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as COSV60518223; called by muse, mutect2, varscan2
- ROBO2 | c.3296A>G p.Y1099C | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.693); catalogued as rs372099694; called by muse, mutect2, varscan2
- RPAP3 | c.1390A>T p.N464Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV50042726; called by muse, mutect2, varscan2
- SAGE1 | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61016889; called by muse, mutect2, varscan2
- SDHAF4 | c.102T>G p.S34R | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.278); catalogued as COSV65085568; called by muse, mutect2, varscan2
- SDK2 | c.5687A>C p.Y1896S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66194413; called by muse, mutect2, varscan2
- SEC14L5 | c.1052T>A p.L351Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52041304; called by muse, mutect2, varscan2
- SEC31A | c.683A>C p.Q228P | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV52350467; called by muse, mutect2
- SH3BP4 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 92/126 reads (73%) | catalogued as COSV60645854; called by muse, mutect2, varscan2
- SHD | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.723); catalogued as COSV73378774; called by muse, mutect2, varscan2
- SIGLEC10 | c.1403C>A p.A468D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59485826; called by muse, mutect2, varscan2
- SLC12A2 | c.1943A>G p.N648S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV52475382, COSV99320463; called by muse, mutect2, varscan2
- SLC25A24 | c.116T>A p.V39E | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV51450245; called by muse, mutect2, varscan2
- SLC36A3 | c.150C>A p.H50Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58858051; called by muse, mutect2, varscan2
- SLCO4C1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV60519385; called by muse, mutect2, varscan2
- SMAD5 | c.464T>G p.V155G | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV72597620; called by muse, mutect2, varscan2
- SMAP2 | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1476155950, COSV65533752; called by muse, mutect2, varscan2
- SORCS3 | c.1744C>G p.P582A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63821500; called by mutect2, varscan2
- SOWAHB | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV57555082; called by muse, varscan2
- SPARC | c.673A>T p.N225Y | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.666); catalogued as COSV50560086; called by muse, mutect2, varscan2
- SPAST | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs768664944, COSV59516846; called by muse, mutect2, varscan2
- SPATA18 | c.850A>T p.R284W | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54649154; called by muse, mutect2, varscan2
- SPOCD1 | c.1858C>A p.L620I | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV57099257, COSV99930019; called by muse, mutect2, varscan2
- SPRR4 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 65/226 reads (29%) | catalogued as COSV60143198; called by muse, mutect2, varscan2
- SREK1IP1 | c.256A>T p.K86* | Nonsense Mutation (SNP) | VAF 50/189 reads (26%) | catalogued as COSV72486403; called by muse, mutect2, varscan2
- STAC | c.156A>T p.L52F | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV56216705; called by muse, mutect2, varscan2
- STK17A | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV60048455; called by muse, mutect2, varscan2
- STK31 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV63458844; called by muse, mutect2, varscan2
- STK39 | c.432T>A p.G144= | Splice Region (SNP) | VAF 16/87 reads (18%) | catalogued as COSV63600612; called by muse, mutect2, varscan2
- SUFU | c.1427A>T p.D476V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV64019751; called by muse, mutect2, varscan2
- TAOK1 | c.1217A>G p.Y406C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55597446; called by muse, mutect2, varscan2
- TG | c.4694G>C p.C1565S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55090975; called by muse, mutect2, varscan2
- TGFBRAP1 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); catalogued as COSV51515323; called by muse, mutect2, varscan2
- THAP9 | c.1604T>A p.L535Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56357474; called by muse, mutect2, varscan2
- TMC1 | c.1702T>G p.Y568D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52783509; called by muse, mutect2, varscan2
- TMEM131 | c.1735A>G p.I579V | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs972533717, COSV51784287; called by muse, mutect2, varscan2
- TMEM183A | c.749A>C p.Q250P | Missense Mutation (SNP) | VAF 114/279 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV65888064; called by muse, mutect2, varscan2
- TNNC2 | c.202A>C p.S68R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65333131; called by muse, mutect2, varscan2
- TOGARAM1 | c.2018A>T p.Q673L | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV61889213; called by muse, mutect2, varscan2
- TRAPPC6A | c.248A>G p.D83G (on ENST00000585934 / NM_001270891.2; = p.D97G on NM_024108.3) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50065445; called by muse, mutect2, varscan2
- TRIM27 | c.847A>T p.K283* | Nonsense Mutation (SNP) | VAF 40/185 reads (22%) | catalogued as COSV65873982; called by muse, mutect2, varscan2
- TRIM6 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs971719179, COSV53478569; called by muse, mutect2, varscan2
- TTN | c.4628T>A p.V1543E (on ENST00000591111; = p.V1497E on NM_003319.4) | Missense Mutation (SNP) | VAF 34/52 reads (65%) | PolyPhen possibly damaging (0.448); catalogued as COSV60285249; called by muse, mutect2, varscan2
- UBP1 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs778346234, COSV52147350; called by mutect2, varscan2
- ULK2 | c.760A>G p.R254G | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV64447904; called by muse, mutect2, varscan2
- USP19 | c.2588A>T p.Y863F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV60048035; called by muse, mutect2, varscan2
- VENTX | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58085260; called by muse, mutect2, varscan2
- VSTM1 | c.174T>A p.F58L | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV58076434; called by muse, mutect2, varscan2
- VTN | c.758A>T p.N253I | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV56874722; called by muse, mutect2, varscan2
- WBP4 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as COSV65274551; called by muse, mutect2, varscan2
- WFS1 | c.280A>T p.R94W | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV56991146; called by muse, mutect2, varscan2
- YIPF1 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50779188; called by muse, mutect2, varscan2
- YTHDC2 | c.73T>C p.C25R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1007614690, COSV50750949; called by muse, mutect2, varscan2
- ZC3H12C | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53712301; called by muse, mutect2, varscan2
- ZFHX3 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs142256050; called by muse, mutect2, varscan2
- ZFP41 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV58088188; called by muse, mutect2
- ZNF208 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.109); catalogued as rs530559517, COSV68111508, COSV68111924; called by muse, mutect2, varscan2
- ZNF273 | c.1261A>G p.K421E | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV60400331; called by muse, mutect2, varscan2
- ZNF311 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV65853342; called by muse, mutect2
- ZNF334 | c.1021A>T p.R341W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61619864; called by muse, mutect2, varscan2
- ZNF347 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV61969972, COSV61970543; called by muse, mutect2, varscan2
- ZNF408 | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV61239072; called by muse, mutect2, varscan2
- ZNF518A | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV60153020; called by muse, mutect2, varscan2
- ZNF578 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.954); catalogued as COSV69737400; called by muse, mutect2, varscan2
- FIGNL1 | c.926dup p.Y310Vfs*22 | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | called by mutect2, varscan2
- HORMAD1 | c.915del p.E306Kfs*15 | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by mutect2, pindel, varscan2
- LPO | c.1581del p.N527Kfs*3 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.751); called by muse, mutect2
- OR12D3 | c.623del p.A208Vfs*4 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- PRC1 | c.1035dup p.E346* | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- PRICKLE4 | c.764_765dup p.L256Afs*61 (on ENST00000359201; = p.L296Afs*61 on NM_013397.6) | Frame Shift Ins (INS) | VAF 50/81 reads (62%) | called by mutect2, varscan2
- TP53 | c.949_978del p.Q317_E326del | In Frame Del (DEL) | VAF 18/23 reads (78%) | called by mutect2, pindel*, varscan2*
- ADCY8 | c.3144T>A p.P1048= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV53923232; called by muse, mutect2
- ADGRL4 | c.315C>A p.T105= | Silent (SNP) | VAF 52/123 reads (42%) | catalogued as COSV66064844; called by muse, mutect2, varscan2
- AFDN | c.4167A>T p.P1389= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV60054061; called by muse, mutect2, varscan2
- ANOS1 | c.1749T>A p.T583= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV52925131; called by muse, mutect2, varscan2
- AQP10 | c.534G>C p.L178= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV61476003; called by muse, mutect2, varscan2
- ASCC1 | c.891A>G p.K297= (on ENST00000342444 / NM_001369085.1; = p.K269= on NM_001198798.2 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV57728382; called by muse, mutect2, varscan2
- ATF6B | c.1341A>T p.P447= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV64352530; called by muse, mutect2, varscan2
- ATP1A2 | c.1044C>A p.R348= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV63405546; called by muse, mutect2, varscan2
- BOC | c.3108C>T p.A1036= | Silent (SNP) | VAF 65/103 reads (63%) | catalogued as rs777774107, COSV56356658; called by muse, mutect2, varscan2
- BOD1L1 | c.900A>G p.L300= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV50047198; called by muse, mutect2, varscan2
- C2CD5 | c.717A>T p.I239= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV61727153; called by muse, mutect2, varscan2
- CD109 | c.108C>T p.I36= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs776339213, COSV54655455; called by muse, mutect2, varscan2
- CHAT | c.2196A>G p.P732= | Silent (SNP) | VAF 42/60 reads (70%) | catalogued as COSV60331620; called by muse, mutect2, varscan2
- CHERP | c.1836C>T p.F612= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as rs1281784169, COSV52227221; called by muse, mutect2, varscan2
- CMIP | c.654C>A p.T218= (on ENST00000537098 / NM_198390.2; = p.T124= on NM_030629.3) | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV67700063; called by muse, mutect2, varscan2
- CR2 | c.2580G>T p.G860= | Silent (SNP) | VAF 57/108 reads (53%) | catalogued as COSV100889562; called by muse, mutect2, varscan2
- CSPP1 | c.3699C>T p.F1233= (on ENST00000676605; = p.F1192= on NM_024790.6) | Silent (SNP) | VAF 88/168 reads (52%) | catalogued as rs771696486, COSV51591143; called by muse, mutect2, varscan2
- CYP4F22 | c.6G>A p.L2= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV54111131; called by muse, mutect2, varscan2
- EPHA4 | c.2331A>T p.A777= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV56042130; called by muse, mutect2, varscan2
- EYA1 | c.450T>A p.G150= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV58171891, COSV58175088; called by muse, mutect2, varscan2
- FAM114A2 | c.324A>G p.S108= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as COSV61078595; called by muse, mutect2, varscan2
- FARP2 | c.1374C>A p.A458= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as COSV50878931; called by muse, mutect2, varscan2
- FBXO10 | c.192A>G p.P64= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs1470673830, COSV52835056; called by muse, mutect2, varscan2
- FLG | c.2445A>T p.G815= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV100911271; called by muse, varscan2
- FLG2 | c.3606C>A p.S1202= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs1360655927, COSV66172100; called by muse, mutect2, varscan2
- FLRT1 | c.208C>A p.R70= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as rs139162750, COSV55366155; called by muse, mutect2, varscan2
- HOXA11 | c.255G>T p.A85= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV50054311; called by muse, mutect2, varscan2
- IL12RB1 | c.645G>T p.L215= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV59098856; called by muse, mutect2, varscan2
- IL13RA2 | c.732T>C p.L244= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV54567203; called by muse, mutect2, varscan2
- INPPL1 | c.3472C>T p.L1158= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1273181324, COSV53358686; called by muse, mutect2, varscan2
- INSYN2A | c.990G>C p.G330= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV54755943; called by muse, mutect2, varscan2
- JAKMIP2 | c.667C>T p.L223= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV54613744, COSV99508354; called by muse, mutect2, varscan2
- KIF26B | c.4527C>A p.V1509= | Silent (SNP) | VAF 113/204 reads (55%) | catalogued as COSV100832852, COSV63649712; called by muse, mutect2, varscan2
- MARVELD2 | c.468G>A p.R156= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV57782040; called by muse, mutect2, varscan2
- MEF2A | c.519A>G p.T173= (on ENST00000557942 / NM_001319206.2; = p.T175= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV57536692; called by muse, mutect2, varscan2
- MIPEP | c.1551G>A p.R517= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1216178185, COSV66301717; called by muse, mutect2, varscan2
- MITF | c.1065A>G p.R355= (on ENST00000448226 / NM_006722.3; = p.R255= on NM_000248.4) | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as COSV100096357, COSV100096872, COSV58835204; called by muse, mutect2, varscan2
- MRC1 | c.3891A>C p.I1297= | Silent (SNP) | VAF 91/359 reads (25%) | called by muse, mutect2, varscan2
- MUC16 | c.21858T>A p.S7286= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV67487654; called by muse, mutect2, varscan2
- MUC4 | c.2766C>A p.I922= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV62186476; called by muse, mutect2, varscan2
- NAV3 | c.604C>A p.R202= | Silent (SNP) | VAF 81/196 reads (41%) | catalogued as COSV57080262, COSV57106346, COSV99887406; called by muse, mutect2, varscan2
- NCOA2 | c.4287C>T p.P1429= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs781256206, COSV51222412, COSV99144981; called by muse, mutect2, varscan2
- NEPRO | c.120A>T p.A40= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV58724291; called by muse, mutect2, varscan2
- NOX3 | c.180C>T p.C60= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV50161120; called by muse, mutect2, varscan2
- OR2B2 | c.537T>C p.C179= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV57580552; called by muse, mutect2, varscan2
- OR4F6 | c.549A>G p.R183= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as rs1423600033, COSV61027466; called by muse, mutect2, varscan2
- OR5B17 | c.195T>C p.S65= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV62160928; called by muse, mutect2, varscan2
- PLEC | c.3855C>T p.A1285= (on ENST00000322810 / NM_201380.4; = p.A1175= on NM_000445.5) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs782313733, COSV59683969; called by muse, mutect2, varscan2
- PLXNB1 | c.4464A>T p.A1488= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV56493497; called by muse, varscan2
- PPP2R5E | c.774A>G p.A258= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs773128001, COSV61743903; called by muse, mutect2, varscan2
- PRDM2 | c.3948A>T p.T1316= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV52454090; called by muse, mutect2, varscan2
- PREX1 | c.1488C>T p.Y496= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs760779791, COSV64255813; called by muse, mutect2, varscan2
- PRPF6 | c.39G>T p.A13= | Silent (SNP) | VAF 62/104 reads (60%) | catalogued as COSV53877200; called by muse, mutect2, varscan2
- PSG2 | c.741A>G p.S247= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV61546264; called by muse, mutect2, varscan2
- PTPRZ1 | c.4434T>A p.S1478= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV66444098; called by muse, mutect2, varscan2
- RASA3 | c.1833C>A p.T611= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV61872287; called by muse, mutect2, varscan2
- RCSD1 | c.258T>A p.I86= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV63260680; called by muse, mutect2, varscan2
- RLIM | c.474A>G p.P158= | Silent (SNP) | VAF 39/45 reads (87%) | catalogued as rs1455410643, COSV60328690; called by muse, mutect2, varscan2
- SF3B4 | c.546C>T p.S182= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV54966684; called by muse, mutect2, varscan2
- SIGLEC1 | c.3342G>T p.P1114= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV52470669; called by muse, mutect2, varscan2
- SIGLEC9 | c.846T>A p.P282= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV51587381; called by muse, mutect2, varscan2
- SIN3B | c.1281A>C p.T427= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV56135946; called by muse, mutect2, varscan2
- SPICE1 | c.942A>G p.S314= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV55623996; called by muse, mutect2, varscan2
- ST3GAL3 | c.1113A>G p.K371= (on ENST00000361392 / NM_174964.4; = p.K356= on NM_006279.5) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1015506821, COSV53519339; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SULT1B1 | c.22C>T p.L8= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV60209120; called by muse, mutect2, varscan2
- SUPT6H | c.3393C>T p.S1131= | Silent (SNP) | VAF 93/195 reads (48%) | catalogued as COSV58930748; called by muse, mutect2, varscan2
- SYNE1 | c.13170C>T p.I4390= (on ENST00000367255 / NM_182961.4; = p.I4319= on NM_033071.3) | Silent (SNP) | VAF 69/101 reads (68%) | catalogued as COSV55076021; called by muse, mutect2, varscan2
- TMEM168 | c.1542A>T p.L514= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV57182156; called by muse, mutect2, varscan2
- WDFY3 | c.8523A>C p.A2841= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV55711817; called by muse, mutect2, varscan2
- CLU | c.-46C>G | 5'UTR (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100324184; called by muse, mutect2, varscan2
- MBD1 | c.793-153G>A | Intron (SNP) | VAF 13/20 reads (65%) | catalogued as rs372009396; called by muse, mutect2, varscan2
- ZNF766 | c.19-243A>G | Intron (SNP) | VAF 14/74 reads (19%) | catalogued as COSV63010157; called by muse, mutect2, varscan2
